Somatic mutation profile of tumor specimen TARGET-10-PARBSW-09A (aliquot TARGET-10-PARBSW-09A-01D) from TARGET case TARGET-10-PARBSW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,187 days).
Specimen TARGET-10-PARBSW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 040b536e-a66a-4826-b48e-cf929ba6cdec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBSW-10A (Blood Derived Normal), aliquot TARGET-10-PARBSW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b059d0c-4b12-4a24-91f8-57fbec4edd89

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 4, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACBD6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777457819, COSV62571410, COSV62574403; called by muse, mutect2
- CLEC19A | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1344574222; called by muse, mutect2
- DOCK1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as rs1389761562; called by muse, mutect2, varscan2
- FAM13B | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs749443684; called by muse, mutect2, varscan2
- FGFR1 | c.2092G>A p.G698S (on ENST00000447712 / NM_023110.3; = p.G696S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58332939; called by muse, mutect2, varscan2
- GPR75 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs369270021, COSV61828358; called by muse, mutect2, varscan2
- MLN | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs746105078, COSV99803045; called by muse, mutect2, varscan2
- NAP1L2 | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV65172285; called by muse, mutect2, varscan2
- WDR27 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs189652264; called by muse, mutect2, varscan2
- ZNF532 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs373691715; called by muse, mutect2, varscan2
- ATG16L2 | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- C17orf78 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- F8 | c.4744G>A p.D1582N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF2B | c.949T>A p.F317I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MACF1 | c.16161G>C p.Q5387H (on ENST00000372915; = p.Q3320H on NM_012090.5) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- OR2B3 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN2 | c.6939+5G>A | Splice Region (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- SWT1 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- TTN | c.21845C>T p.S7282L (on ENST00000591111; = p.S6355L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | PolyPhen possibly damaging (0.845); called by muse, mutect2
- ZMYM2 | c.3688A>T p.K1230* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- CDH10 | c.1845C>T p.I615= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs756815430, COSV52574073; called by muse, mutect2, varscan2
- ERC2 | c.1722G>A p.T574= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs749483573, COSV55601327; called by muse, mutect2, varscan2
- GABRA1 | c.150A>T p.L50= | Silent (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- GPATCH8 | c.96G>A p.A32= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs141918339; called by muse, mutect2, varscan2
- MYH11 | c.1080C>T p.V360= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- OTUD5 | c.1476G>A p.A492= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs782432323; called by muse, mutect2, varscan2
- TPR | c.774G>A p.L258= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV66603620; called by muse, mutect2
- ZNF717 | c.1803C>A p.I601= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV68869363; called by muse, mutect2, varscan2
- ATG16L2 | c.825-203C>A | Intron (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- CRYM-AS1 | n.320G>T | RNA (SNP) | VAF 78/159 reads (49%) | called by muse, mutect2, varscan2
- LYAR | c.-14C>A | 5'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- MEG3 | n.1040-1318G>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- MMP28 | c.1169-83C>A | Intron (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- OBSCN | c.11660-2818C>G | Intron (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
